Somatic mutation profile of tumor specimen TCGA-63-A5MG-01A (aliquot TCGA-63-A5MG-01A-12D-A27K-08) from TCGA case TCGA-63-A5MG, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IB.
Specimen TCGA-63-A5MG-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bed1c910-0ed3-46da-bc6a-b50d6ff5701b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-63-A5MG-10A (Blood Derived Normal), aliquot TCGA-63-A5MG-10A-01D-A27N-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2ef6091e-285a-451c-bf0d-d8bf436240d2

The open-access MAF lists 112 somatic variants for this specimen: 85 protein-altering or splice-affecting, 24 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 72, Silent 24, Nonsense Mutation 5, Splice Region 2, Splice Site 2, Intron 2, Frame Shift Del 2, Translation Start Site 2, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.493-2A>G p.X165_splice | Splice Site (SNP) | VAF 10/79 reads (13%) | catalogued as rs587781784, CS075218, COSV64297091, COSV64308401; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA4 | c.3349A>T p.T1117S | Missense Mutation (SNP) | VAF 6/89 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV100933089; called by muse, mutect2
- ADGRL4 | c.1643C>T p.S548L | Missense Mutation (SNP) | VAF 11/172 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs191635062; called by muse, mutect2
- ADGRV1 | c.2996G>A p.R999K | Missense Mutation (SNP) | VAF 3/8 reads (38%) | SIFT tolerated (0.88); PolyPhen benign (0.012); catalogued as COSV101315729, COSV67981041; called by muse, mutect2
- AEBP1 | c.1513A>T p.T505S | Missense Mutation (SNP) | VAF 20/100 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV99788632; called by muse, mutect2, varscan2
- ALPK2 | c.3196A>G p.I1066V | Missense Mutation (SNP) | VAF 14/119 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV100864277; called by muse, mutect2, varscan2
- ANGPT1 | c.565G>T p.E189* | Nonsense Mutation (SNP) | VAF 11/40 reads (28%) | catalogued as COSV52438764, COSV99862476; called by muse, mutect2, varscan2
- ANKRD26 | c.4311G>T p.M1437I | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.316); catalogued as COSV101063098, COSV65776183; called by muse, mutect2, varscan2
- AP5Z1 | c.1307T>G p.F436C | Missense Mutation (SNP) | VAF 47/242 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV100804071; called by muse, mutect2, varscan2
- ARMCX3 | c.927T>A p.F309L | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.449); catalogued as COSV100362219; called by muse, mutect2, varscan2
- ASB11 | c.724G>A p.E242K | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); catalogued as COSV100728992; called by muse, mutect2, varscan2
- ASH1L | c.3468G>C p.K1156N | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.296); catalogued as COSV100853312; called by muse, mutect2, varscan2
- ATP13A5 | c.981G>T p.Q327H | Missense Mutation (SNP) | VAF 11/119 reads (9%) | SIFT tolerated (0.7); PolyPhen benign (0.007); catalogued as rs200088291, COSV100664967; called by muse, mutect2, varscan2
- BFSP1 | c.736-1G>T p.X246_splice | Splice Site (SNP) | VAF 9/91 reads (10%) | catalogued as COSV64899492; called by muse, mutect2
- BRSK1 | c.1190G>T p.R397L | Missense Mutation (SNP) | VAF 24/162 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV100473877, COSV100473906; called by muse, mutect2, varscan2
- BTBD7 | c.1394A>T p.K465I | Missense Mutation (SNP) | VAF 23/95 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV100597679; called by muse, mutect2, varscan2
- CD163L1 | c.3253G>A p.A1085T | Missense Mutation (SNP) | VAF 20/153 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs1242468551, COSV100549927; called by muse, mutect2, varscan2
- CDC25A | c.1514G>A p.S505N | Missense Mutation (SNP) | VAF 23/106 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV100207426; called by muse, mutect2, varscan2
- CDH17 | c.648G>T p.M216I | Missense Mutation (SNP) | VAF 24/92 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.813); catalogued as COSV99217248; called by muse, mutect2, varscan2
- CDH23 | c.347G>T p.R116L | Missense Mutation (SNP) | VAF 26/149 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.105); catalogued as COSV54947164, COSV99820158; called by muse, mutect2, varscan2
- CHRM2 | c.1344G>T p.K448N | Missense Mutation (SNP) | VAF 22/107 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV57769065, COSV57780322; called by muse, mutect2, varscan2
- CUX1 | c.2447G>A p.R816H | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.67); catalogued as rs374783479; called by muse, mutect2, varscan2
- DMTF1 | c.433A>T p.T145S | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.35); PolyPhen benign (0.029); catalogued as COSV100487342; called by muse, mutect2, varscan2
- DNAJC13 | c.2903T>A p.M968K | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV99607033; called by muse, mutect2, varscan2
- DNAJC13 | c.2904G>T p.M968I | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as COSV99607036; called by muse, mutect2, varscan2
- DSEL | c.2965G>C p.D989H | Missense Mutation (SNP) | VAF 4/78 reads (5%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV100025501; called by muse, mutect2
- EP400 | c.7887G>T p.T2629= | Splice Region (SNP) | VAF 14/43 reads (33%) | catalogued as rs530971555, COSV100200936; called by muse, mutect2, varscan2
- EREG | c.503A>C p.Q168P | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV99791681; called by muse, mutect2, varscan2
- ERICH3 | c.2854G>T p.D952Y | Missense Mutation (SNP) | VAF 11/161 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV100443933; called by muse, mutect2
- GALNT13 | c.554G>T p.R185L | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101222537, COSV67215488; called by muse, mutect2, varscan2
- HSDL1 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 12/69 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.452); catalogued as COSV99550325; called by muse, mutect2, varscan2
- HTR3E | c.1243G>T p.A415S (on ENST00000415389 / NM_001256613.1; = p.A430S on NM_182589.2) | Missense Mutation (SNP) | VAF 27/106 reads (25%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.832); catalogued as rs1320975835, COSV100093909; called by muse, mutect2
- IGSF1 | c.3417C>A p.D1139E | Missense Mutation (SNP) | VAF 52/203 reads (26%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.956); catalogued as COSV100812020; called by muse, mutect2, varscan2
- IQSEC3 | c.3021C>A p.C1007* (on ENST00000538872 / NM_001170738.2; = p.C704* on NM_015232.1) | Nonsense Mutation (SNP) | VAF 10/124 reads (8%) | catalogued as COSV100407040, COSV58292841; called by muse, mutect2
- KCNK2 | c.157A>G p.T53A (on ENST00000444842 / NM_001017425.3; = p.T38A on NM_014217.4) | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated, low confidence (0.78); PolyPhen benign (0); catalogued as rs1247237657, COSV101222027; called by muse, mutect2, varscan2
- KLC4 | c.595G>A p.A199T | Missense Mutation (SNP) | VAF 8/179 reads (4%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.989); catalogued as COSV99431689; called by muse, mutect2
- LARGE1 | c.653G>A p.G218E | Missense Mutation (SNP) | VAF 14/118 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100505867; called by muse, mutect2, varscan2
- LMTK2 | c.676C>G p.L226V | Missense Mutation (SNP) | VAF 13/113 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.874); catalogued as COSV99806558, COSV99806786; called by muse, mutect2, varscan2
- LRP1B | c.11845A>T p.K3949* | Nonsense Mutation (SNP) | VAF 6/52 reads (12%) | catalogued as COSV101255051, COSV67185367; called by muse, mutect2, varscan2
- LRRC8C | c.1007A>G p.Y336C | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100968188; called by muse, mutect2, varscan2
- MAT1A | c.115G>T p.D39Y | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100944418; called by muse, mutect2, varscan2
- MBD5 | c.655G>A p.G219R | Missense Mutation (SNP) | VAF 20/123 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs368093794; called by muse, mutect2, varscan2
- MED16 | c.1701C>G p.H567Q | Missense Mutation (SNP) | VAF 19/121 reads (16%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.995); catalogued as COSV99515440; called by muse, mutect2, varscan2
- MLLT10 | c.479A>G p.H160R | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100307856; called by muse, mutect2, varscan2
- MSTN | c.946G>C p.V316L | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV99640623; called by muse, mutect2, varscan2
- MUC6 | c.2735C>A p.T912K | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101424501; called by muse, mutect2, varscan2
- MYT1 | c.622G>T p.E208* | Nonsense Mutation (SNP) | VAF 14/80 reads (18%) | catalogued as COSV100114387, COSV60513530; called by muse, mutect2, varscan2
- NAPSA | c.202G>A p.V68I | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.766); catalogued as rs1247407466, COSV99515792; called by muse, mutect2, varscan2
- NLRP8 | c.1481G>A p.R494Q | Missense Mutation (SNP) | VAF 31/207 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.02); catalogued as rs1436407482, COSV52583532; called by muse, mutect2, varscan2
- NPHP3 | c.1144G>T p.A382S | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.11); catalogued as COSV100446748; called by muse, mutect2
- NRIP1 | c.1179G>T p.M393I | Missense Mutation (SNP) | VAF 21/169 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as rs377732400, COSV100012545; called by muse, mutect2, varscan2
- OR4C13 | c.247T>A p.S83T | Missense Mutation (SNP) | VAF 32/205 reads (16%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.066); catalogued as COSV101634158, COSV73648840; called by muse, mutect2, varscan2
- OR5I1 | c.429T>A p.C143* | Nonsense Mutation (SNP) | VAF 15/86 reads (17%) | catalogued as COSV100041332; called by muse, mutect2, varscan2
- OR5M10 | c.422G>T p.C141F | Missense Mutation (SNP) | VAF 21/118 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.443); catalogued as COSV101595875, COSV101595905; called by muse, mutect2, varscan2
- OR5R1 | c.256G>T p.V86F | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.467); catalogued as COSV100393368, COSV56571782; called by muse, mutect2, varscan2
- PAPPA | c.997G>C p.D333H | Missense Mutation (SNP) | VAF 5/60 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100073565; called by muse, mutect2
- PAPPA2 | c.1962G>C p.K654N | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV100866709; called by muse, mutect2, varscan2
- PCDHB8 | c.820G>C p.V274L | Missense Mutation (SNP) | VAF 31/280 reads (11%) | SIFT tolerated, low confidence (0.74); PolyPhen benign (0.007); catalogued as COSV99176693; called by muse, mutect2, varscan2
- PIR | c.5G>T p.G2V | Missense Mutation (SNP) | VAF 18/106 reads (17%) | SIFT tolerated (0.62); PolyPhen benign (0.007); catalogued as COSV100712679; called by muse, mutect2, varscan2
- PLXNA4 | c.3547G>T p.V1183L | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100323606; called by muse, mutect2, varscan2
- POU3F4 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 6/34 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.495); catalogued as COSV100937196; called by muse, mutect2, varscan2
- PRKG1 | c.699C>A p.S233R | Missense Mutation (SNP) | VAF 16/107 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.822); catalogued as COSV100908096; called by muse, mutect2, varscan2
- PRR30 | c.1082G>T p.R361M | Missense Mutation (SNP) | VAF 32/177 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV99574423; called by muse, mutect2, varscan2
- RAB6B | c.72C>G p.V24= | Splice Region (SNP) | VAF 10/117 reads (9%) | catalogued as COSV99557915; called by muse, mutect2
- RAD1 | c.130G>A p.A44T | Missense Mutation (SNP) | VAF 16/130 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.029); catalogued as rs944974848, COSV100337568; called by muse, mutect2, varscan2
- RYR1 | c.11793C>G p.D3931E | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV100615357, COSV100615420; called by muse, mutect2, varscan2
- RYR3 | c.10292A>G p.Y3431C (on ENST00000389232; = p.Y3432C on NM_001036.6) | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs978771459, COSV101212441; called by muse, mutect2, varscan2
- SLC17A6 | c.527A>G p.H176R | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.904); catalogued as COSV99581217; called by muse, mutect2, varscan2
- SLC22A9 | c.266G>A p.R89H | Missense Mutation (SNP) | VAF 11/136 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.081); catalogued as rs374063102; called by muse, mutect2
- SPAG16 | c.1300G>A p.G434R | Missense Mutation (SNP) | VAF 30/111 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV59105945; called by muse, mutect2, varscan2
- SYNE1 | c.20366G>T p.R6789I (on ENST00000367255 / NM_182961.4; = p.R6718I on NM_033071.3) | Missense Mutation (SNP) | VAF 20/133 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99559409; called by muse, mutect2, varscan2
- TEX47 | c.748C>A p.P250T | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.207); catalogued as COSV99787235; called by muse, mutect2, varscan2
- THEMIS | c.889C>G p.P297A | Missense Mutation (SNP) | VAF 18/114 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.012); catalogued as COSV100965323, COSV64069383; called by muse, mutect2, varscan2
- THSD7B | c.1412C>A p.P471Q | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99747996; called by muse, mutect2
- TMPRSS13 | c.1453G>A p.V485I | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.169); catalogued as COSV101471424; called by muse, mutect2, varscan2
- TNFAIP3 | c.47G>A p.R16Q | Missense Mutation (SNP) | VAF 10/107 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.276); catalogued as rs759654484, COSV99396578; called by muse, mutect2
- TSGA10 | c.1281G>T p.W427C | Missense Mutation (SNP) | VAF 14/109 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV100747489; called by muse, mutect2, varscan2
- TTN | c.39149C>G p.T13050R (on ENST00000591111; = p.T5626R on NM_003319.4) | Missense Mutation (SNP) | VAF 6/106 reads (6%) | PolyPhen probably damaging (0.998); catalogued as COSV100604522; called by muse, mutect2
- VGLL3 | c.383G>C p.G128A | Missense Mutation (SNP) | VAF 14/232 reads (6%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.696); catalogued as COSV101051898, COSV67352404; called by muse, mutect2
- ZNF135 | c.1807G>A p.E603K (on ENST00000313434 / NM_001289401.2; = p.E615K on NM_003436.4) | Missense Mutation (SNP) | VAF 20/136 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as COSV100536545; called by muse, mutect2, varscan2
- ZNF208 | c.1979C>T p.A660V | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.233); catalogued as COSV101236974, COSV101236985; called by muse, varscan2
- ZNF208 | c.1978G>T p.A660S | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.042); catalogued as rs878946412, COSV101236975; called by muse, varscan2
- ZSWIM5 | c.2565T>A p.S855R | Missense Mutation (SNP) | VAF 64/376 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.438); catalogued as COSV100655484; called by muse, mutect2, varscan2
- ARID2 | c.155_156del p.T52Kfs*13 | Frame Shift Del (DEL) | VAF 5/70 reads (7%) | called by mutect2, pindel*
- CLMN | c.1268del p.K423Rfs*35 | Frame Shift Del (DEL) | VAF 38/157 reads (24%) | called by mutect2, pindel, varscan2
- CD28 | c.588C>T p.P196= | Silent (SNP) | VAF 16/184 reads (9%) | catalogued as COSV100142329; called by muse, mutect2
- CSMD3 | c.6063G>A p.T2021= (on ENST00000297405 / NM_001363185.1; = p.T1917= on NM_052900.3) | Silent (SNP) | VAF 24/125 reads (19%) | catalogued as rs150436177, COSV52368262; called by muse, mutect2, varscan2
- GDF3 | c.972C>T p.I324= | Silent (SNP) | VAF 16/96 reads (17%) | catalogued as COSV100325225; called by muse, mutect2, varscan2
- IL13RA2 | c.435C>T p.C145= | Silent (SNP) | VAF 19/41 reads (46%) | catalogued as rs199528071, COSV54565300; called by muse, mutect2, varscan2
- IL27 | c.130C>A p.R44= | Silent (SNP) | VAF 11/79 reads (14%) | catalogued as rs747064370, COSV100795850, COSV63559617; called by muse, mutect2, varscan2
- MTG2 | c.951G>A p.P317= | Silent (SNP) | VAF 51/378 reads (13%) | catalogued as rs139683821; called by muse, mutect2, varscan2
- MYBPH | c.1350G>A p.G450= | Silent (SNP) | VAF 16/208 reads (8%) | catalogued as COSV99704449; called by muse, mutect2
- NIBAN3 | c.1344C>T p.R448= | Silent (SNP) | VAF 38/273 reads (14%) | catalogued as COSV99961992; called by muse, mutect2, varscan2
- NUDT21 | c.357A>G p.E119= | Silent (SNP) | VAF 15/63 reads (24%) | catalogued as COSV100272987; called by muse, mutect2, varscan2
- OR1L1 | c.378C>T p.V126= (on ENST00000373686; = p.V76= on NM_001005236.3) | Silent (SNP) | VAF 10/154 reads (6%) | catalogued as COSV100542115; called by muse, mutect2
- OR8B3 | c.870T>C p.S290= | Silent (SNP) | VAF 12/90 reads (13%) | catalogued as COSV100660390; called by mutect2, varscan2
- PIK3CA | c.552A>G p.K184= | Silent (SNP) | VAF 14/102 reads (14%) | catalogued as COSV99836126; called by muse, mutect2, varscan2
- PRKAA2 | c.663G>A p.T221= | Silent (SNP) | VAF 14/330 reads (4%) | catalogued as rs1193150275, COSV64803756; called by muse, mutect2
- RXFP2 | c.837G>T p.S279= | Silent (SNP) | VAF 8/61 reads (13%) | catalogued as rs367651871, COSV100034201; called by muse, mutect2, varscan2
- SFXN5 | c.192G>A p.V64= | Silent (SNP) | VAF 8/43 reads (19%) | catalogued as COSV55589346, COSV99729100; called by muse, mutect2, varscan2
- SLC38A10 | c.2220C>T p.D740= | Silent (SNP) | VAF 11/91 reads (12%) | catalogued as rs1450065324, COSV55849620; called by muse, mutect2, varscan2
- TAS2R3 | c.387G>T p.V129= | Silent (SNP) | VAF 40/170 reads (24%) | catalogued as COSV99924497; called by muse, mutect2, varscan2
- TEX19 | c.183T>G p.P61= | Silent (SNP) | VAF 22/116 reads (19%) | catalogued as COSV100331008; called by muse, mutect2, varscan2
- TIMELESS | c.1710T>C p.C570= | Silent (SNP) | VAF 32/174 reads (18%) | catalogued as COSV99973812; called by muse, mutect2, varscan2
- TMEM208 | c.234G>A p.A78= | Silent (SNP) | VAF 5/47 reads (11%) | catalogued as rs764209424, COSV99264000; called by mutect2, varscan2
- UNC93A | c.42G>T p.G14= | Silent (SNP) | VAF 15/105 reads (14%) | catalogued as COSV100023234; called by muse, mutect2, varscan2
- USP15 | c.2565T>C p.P855= (on ENST00000280377 / NM_001351159.2; = p.P826= on NM_006313.3 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 22/94 reads (23%) | catalogued as COSV99739102; called by muse, mutect2, varscan2
- USP29 | c.1071C>A p.V357= | Silent (SNP) | VAF 11/83 reads (13%) | catalogued as COSV54142282, COSV99517939; called by muse, mutect2, varscan2
- ZNF257 | c.915A>G p.Q305= | Silent (SNP) | VAF 8/80 reads (10%) | catalogued as rs1444023292, COSV101448083; called by muse, mutect2
- DEFB119 | c.61+1268G>C | Intron (SNP) | VAF 21/119 reads (18%) | catalogued as COSV100190708; called by muse, mutect2, varscan2
- SNORD116-12 | n.62C>G | RNA (SNP) | VAF 15/141 reads (11%) | catalogued as rs1157940173; called by muse, mutect2, varscan2
- SYTL2 | c.1459+2492G>T | Intron (SNP) | VAF 12/116 reads (10%) | catalogued as COSV100314007; called by muse, mutect2
